Gene-level copy-number profile of tumor specimen HCM-BROD-0693-C71-01A from HCMI case HCM-BROD-0693-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 66.3 years (24,222 days).
Specimen HCM-BROD-0693-C71-01A: Sample type: Slides; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 9a639b0f-6e18-41b2-a7a2-4213104da146.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0693-C71-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,713 have no estimate.
https://portal.gdc.cancer.gov/files/c2c1e624-58c7-45d3-b0e0-7a1c5b2769d5

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 3; copy number 2: 6,224; copy number 3: 14,973; copy number 4: 29,356; copy number 5: 6,615; copy number 6: 237; copy number 7: 1,037; copy number 8: 190; copy number 9: 57; copy number 10: 3; copy number 11: 33; copy number 12: 16; copy number 13: 25; copy number 14: 5; copy number 15: 84; copy number 79: 48.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:16,683,438–16,684,227, 1 gene: RNASEH1P2.
- chr17:18,511,221–18,551,705, 3 genes (within-gene range 0–3): FAM106A, USP32P2, SRP68P2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 271 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:2,403,588–2,614,733, 6 genes, copy number 9: CHST12, GRIFIN, LFNG, MIR4648, BRAT1, IQCE.
- chr7:53,926,676–56,882,146, 85 genes, copy number 12–15 (broad region; genes not listed).
- chr7:57,060,590–62,275,678, 55 genes, copy number 11–13: PHKG1P4, AC122133.1, ZNF479, AC099654.11, AC099654.2, MTATP6P8, MTCO3P10, MTND4LP32, MTND4P4, MTND5P6, MTCYBP29, GUSBP10, MTND1P4, MTND2P6, MTCO1P10, MTCO2P10, MTCO3P4, AC099654.7, MTND4P5, MTND5P7, MTCYBP5, GUSBP12, AC099654.1, RNU7-157P, AC099654.3, AC237221.2, AC237221.1, MIR3147, VN1R28P, SAPCD2P2, ZNF716, AC092175.1, NCOR1P3, AC064862.6, AC064862.7, BSNDP4, AC064862.1, AC064862.5, AC064862.2, AC064862.4, AC064862.3, AC023141.4, AC023141.8, AC023141.5, AC023141.12, AC023141.2, AC023141.9, AC023141.11, AC023141.3, AC023141.1, AC023141.10, AC023141.6, AC023141.7, AC023141.13, AC128676.1.
- chr7:83,355,154–83,362,266, 1 gene, copy number 12: AC079799.1.
- chr7:112,328,189–112,521,670, 10 genes, copy number 12 (within-gene range 4–12): AC004112.1, MTND5P8, MTND6P24, MTCYBP24, IFRD1, AC079741.1, AC005192.1, AC079741.2, LSMEM1, NPM1P14.
- chr7:132,784,870–136,437,785, 51 genes, copy number 9: CHCHD3, AC009365.3, AC008038.1, MIR3654, RNU6-92P, ST13P7, EXOC4, MIR6133, AC083875.1, COX5BP3, RPS3AP27, LRGUK, AC008154.2, SLC35B4, AC008154.1, AC009275.1, AKR1B1, AKR1B10, AKR1B15, BPGM, AC009276.1, TUBB3P2, CALD1, AC083870.1, AGBL3, CYREN, RNF14P4, TMEM140, AC083862.1, WDR91, AC009542.1, MIR6509, STRA8, SLC23A4P, CNOT4, SDHDP2, NUP205, AC093107.2, AC093107.1, STMP1, RNU6-1154P, SLC13A4, AC091736.1, FAM180A, AC015987.1, MTPN, RNU6-223P, AC024084.1, AC078845.1, Y_RNA, AC009784.1.
- chr7:138,460,259–138,701,362, 5 genes, copy number 14 (within-gene range 5–14): TRIM24, RPS3AP28, SVOPL, AC013429.2, AC013429.1.
- chr12:57,243,453–57,431,005, 3 genes, copy number 10 (within-gene range 4–10): STAC3, AC137834.1, R3HDM2.
- chr12:57,434,784–57,984,761, 48 genes, copy number 79: INHBC, INHBE, AC022506.2, GLI1, ARHGAP9, MARS1, MIR6758, DDIT3, AC022506.1, MIR616, MBD6, DCTN2, KIF5A, PIP4K2C, DTX3, ARHGEF25, AC025165.1, AC025165.6, SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2.
- chr12:58,103,907–58,395,138, 3 genes, copy number 11: AC090643.2, RPL21P103, AC025578.1.
- chr12:58,872,149–59,064,238, 4 genes, copy number 12: LRIG3, AC068305.2, RPS6P22, AC068305.1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
